CCDI case PBCDEM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/af568f89-714b-4e9e-ad37-c4ffe7763eb4

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 17.3 years (6,329 days).

Biospecimens (3 samples)
- Sample 0DPE92: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPE9B: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPE9J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
